Surgical pathology report (de-identified scan), TCGA case TCGA-2A-AAYF, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Memorial Sloan Kettering Cancer Center, specimen TCGA-2A-AAYF-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis & History:

PSA 8.9, cT1c, Gleason 3 + 3

DATE OF TUMOR PROCUREMENT:

Specimens Submitted:

- 1: Prostate and seminal vesicles, radical prostatectomy
- 2: Peri-prostatic fat, excision

DIAGNOSIS:

1. Prostate and seminal vesicles, radical prostatectomy:

Part # 1

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:4

Total Gleason score:7

Tumor Location:

Involves Right posterior

Involves Right anterior

Involves Left anterior

Dominant tumor mass located in: right, anterior, apex to base

Vascular Invasion:

Not Identified

Perineural Invasion:

Identified

Tumor Multicentricity:

Multicentric foci of invasive carcinoma are present

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Established extracapsular extension

The location of the extracapsular extension is right, anterior, close to base

Seminal Vesicles:

Not involved

Bladder Neck:

Not Involved

Surgical Margins:

Free of tumor

ITD 0-3

Adenocarcinoma NOS
8/40/3
Site Prostate NOS
261.9
JW 3/12/14

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Non-Neoplastic Prostate:
Exhibits nodular hyperplasia

Staging (AJCC 1997):

pT3a (extracapsular extension)

2. Peri-prostatic fat, excision:
- Benign fibroadipose tissue

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "Prostate and seminal vesicles".

It consists of a prostate and seminal vesicles.

The total weight is 47.0 grams.

The prostate measures 4.0cm from apex to base, 4.5cm transversely, and 3.5cm from anterior to posterior.

The right and left seminal vesicles measure 4.5 x 1.5 and 3.5 x 1.5 cm, respectively.

The external surface of the prostate is smooth.

The prostate is inked (right=green, left=blue) and fixed in formalin overnight.

The prostate is serially cut from apex to base at approximately 3-4 mm intervals.

The prostate is entirely submitted.

Summary of Sections:

RA-right apical margin

LA-left apical margin

BN-bladder neck margin

RSV-right seminal vesicle

LSV-left seminal vesicle

A-F -serial sections of prostate (apex to base)

2). The specimen is received in formalin, labeled "Peri-prostatic fat" and consists of two portions of yellow lobulated adipose tissue measuring 2.0 x 1.5 x 0.3 and 4.0 x 1.5 x 0.5 cm. No lymph nodes are grossly identified. The specimen is representatively submitted.

Summary of sections:

U- - undesignated

Summary of Sections:

Part 1: Prostate and seminal vesicles, radical prostatectomy

Blocks	Block Designation	PCs
1	A	1
1	B	1
1	BN	1
1	C	1

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

1	D	1
1	E	1
1	F	1
1	LA	1
1	LSV	1
1	RA	1
1	RSV	1

Part 2: Peri-prostatic fat, excision

Blocks	Block Designation	PCs
1	U	2

Special Studies:

Result	Special Stain	Comment
	RECUT	

Per dx discrepancy form, TCGA
tumor is Gleason 3+3.

Criteria	hu 11/15/14	Yes	No

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	PROSTATIC ADENOCARCINOMA GLEASON 3+4=7	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	PROSTATIC ADENOCARCINOMA GLEASON 3+3=6.	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The area of tumor punched for frozen tissue only reflects a portion of the overall tumor. (Tissue Sampling)	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 0bc74d22-ade1-41c5-9c80-619ecee6c288 (TCGA-2A-AAYF.106166DD-946C-4DD0-85CA-5400104959DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).